Somatic mutation profile of cancer-model specimen HCM-BROD-0643-C43-85N (2D Modified Conditionally Reprogrammed Cells, passage 10; aliquot HCM-BROD-0643-C43-85N-01D-A80U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0643-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 53.6 years (19,588 days).
Specimen HCM-BROD-0643-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8f1f96c-e31c-4cea-a1f8-640f75df8e6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0643-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0643-C43-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c991f0d-09f2-4be3-ac03-e142d1a812e8

The open-access MAF lists 297 somatic variants for this specimen: 183 protein-altering or splice-affecting, 106 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 106, Nonsense Mutation 8, Intron 5, Splice Region 4, Frame Shift Del 4, Splice Site 3, 5'UTR 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 187/490 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 240/240 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA7 | c.2332C>T p.R778W | Missense Mutation (SNP) | VAF 232/233 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs751607281; called by muse, mutect2, varscan2
- ADAMTS12 | c.4519G>A p.E1507K | Missense Mutation (SNP) | VAF 175/406 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV61265705; called by muse, mutect2, varscan2
- ADAMTS18 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 171/364 reads (47%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs868333047, COSV51411009, COSV99273813; called by muse, mutect2, varscan2
- ADGRG2 | c.310A>G p.K104E (on ENST00000379869 / NM_001079858.3; = p.K101E on NM_005756.4) | Missense Mutation (SNP) | VAF 170/171 reads (99%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100491844; called by muse, mutect2, varscan2
- ADH1C | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 102/311 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1005267020, COSV72463393; called by muse, mutect2, varscan2
- AFF2 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 326/326 reads (100%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.996); catalogued as rs886044832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALX4 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 265/577 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.098); catalogued as rs959308498; called by muse, varscan2
- ANGPT1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 141/211 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52433501; called by muse, mutect2, varscan2
- ANKRD52 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 242/242 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV57284491; called by muse, mutect2, varscan2
- ARMC4 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 130/130 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV53466824; called by muse, mutect2, varscan2
- ASAH2 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 149/389 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as rs1269772733; called by muse, mutect2, varscan2
- ASAP2 | c.1533del p.K512Nfs*8 | Frame Shift Del (DEL) | VAF 175/479 reads (37%) | catalogued as COSV55631860; called by mutect2, pindel, varscan2
- AZIN2 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 260/504 reads (52%) | catalogued as COSV99613754; called by muse, mutect2, varscan2
- BNC2 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 247/247 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66155565; called by muse, mutect2, varscan2
- BTBD11 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 552/554 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs1319239871; called by muse, mutect2, varscan2
- C11orf24 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 200/1375 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.854); catalogued as rs973677614, COSV58505473; called by muse, mutect2, varscan2
- C4orf19 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 235/346 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1560315176; called by muse, mutect2, varscan2
- CACNA2D4 | c.791G>A p.W264* | Nonsense Mutation (SNP) | VAF 247/495 reads (50%) | catalogued as COSV54950668; called by muse, mutect2, varscan2
- CC2D1B | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 298/507 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs764549898; called by muse, mutect2, varscan2
- CDHR4 | c.862C>G p.R288G | Missense Mutation (SNP) | VAF 146/146 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV58526111; called by muse, mutect2, varscan2
- CENPJ | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 215/480 reads (45%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV101121505; called by muse, mutect2, varscan2
- CFHR4 | c.1592G>A p.G531E (on ENST00000367416 / NM_001201551.2; = p.G285E on NM_006684.5) | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.379); catalogued as COSV52224734; called by muse, mutect2, varscan2
- CLSTN3 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 275/537 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1390323681; called by muse, mutect2, varscan2
- CUX1 | c.31-1G>A p.X11_splice (on ENST00000292535 / NM_181552.4; = p.X22_splice on NM_001913.5) | Splice Site (SNP) | VAF 130/243 reads (53%) | catalogued as COSV99473316; called by muse, mutect2, varscan2
- DEFB125 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 182/352 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66703291; called by muse, mutect2, varscan2
- DLGAP3 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 450/998 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV52394141; called by muse, mutect2, varscan2
- DMBT1 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 317/641 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs759038747, COSV57534000; called by muse, mutect2, varscan2
- DNA2 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 197/364 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs765257819; called by muse, mutect2, varscan2
- DNAH5 | c.7834C>T p.H2612Y | Missense Mutation (SNP) | VAF 159/373 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs1211787821; called by muse, mutect2, varscan2
- DNPEP | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 216/457 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1346102382, COSV56111973; called by muse, mutect2, varscan2
- EDN3 | c.53-1G>A p.X18_splice | Splice Site (SNP) | VAF 149/308 reads (48%) | catalogued as rs746083251, COSV61108409; called by muse, mutect2, varscan2
- EMSY | c.3166C>T p.P1056S | Missense Mutation (SNP) | VAF 256/1137 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58265056; called by muse, mutect2, varscan2
- ESRP1 | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 125/205 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1169738720; called by muse, mutect2, varscan2
- FAM135B | c.2458G>A p.G820R | Missense Mutation (SNP) | VAF 216/339 reads (64%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV52752187; called by muse, mutect2, varscan2
- FAM170B | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 301/538 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as rs868477134, COSV61253906; called by muse, mutect2, varscan2
- FAM187A | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 164/379 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as rs1268355141; called by muse, mutect2, varscan2
- FAM187A | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1283240535; called by muse, mutect2, varscan2
- FGA | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 185/292 reads (63%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs746736351, COSV57393378; called by muse, mutect2, varscan2
- FHL5 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as rs1449031326, COSV58736537; called by muse, mutect2
- FLG | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 131/615 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as rs370228326; called by muse, mutect2, varscan2
- FPR2 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 188/386 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV60671857; called by muse, varscan2
- FSD1 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 168/260 reads (65%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.863); catalogued as rs991859124, COSV55695183; called by muse, mutect2, varscan2
- GIMAP5 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 295/749 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.144); catalogued as COSV57530633; called by muse, mutect2, varscan2
- GIMAP7 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 290/757 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV57958911; called by muse, mutect2, varscan2
- GYS2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 206/463 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV53924583, COSV53929660; called by muse, mutect2, varscan2
- HBE1 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 149/305 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV53079530; called by muse, mutect2, varscan2
- KCNJ15 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 185/410 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60810936; called by muse, mutect2, varscan2
- KIF26B | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 323/786 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63644957; called by muse, mutect2, varscan2
- KLK12 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 184/339 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409744695; called by muse, mutect2, varscan2
- LATS2 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 300/600 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs748263686; called by muse, mutect2
- LGALS16 | c.215G>A p.W72* | Nonsense Mutation (SNP) | VAF 156/306 reads (51%) | catalogued as rs567987381; called by muse, mutect2, varscan2
- LINGO2 | c.699C>G p.D233E | Missense Mutation (SNP) | VAF 244/244 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs757978828; called by muse, mutect2, varscan2
- LRP1B | c.7154G>A p.G2385E | Missense Mutation (SNP) | VAF 226/413 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV67186728; called by muse, mutect2, varscan2
- LRP4 | c.5503G>A p.G1835S | Missense Mutation (SNP) | VAF 184/398 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs752536167; called by muse, varscan2
- MAMDC4 | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 191/191 reads (100%) | SIFT tolerated (0.5); PolyPhen benign (0.05); catalogued as rs141247810; called by muse, mutect2, varscan2
- MEFV | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 280/574 reads (49%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.696); catalogued as rs104895110, CM041800, COSV54826976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM2 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 190/306 reads (62%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.888); catalogued as rs369374390, COSV100036318; called by muse, mutect2, varscan2
- OR10J3 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 172/311 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100171595, COSV59954087; called by muse, mutect2, varscan2
- OR5AK2 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 221/395 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV58804384; called by muse, mutect2, varscan2
- OR6C70 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 153/153 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.32); catalogued as COSV59245411; called by muse, mutect2, varscan2
- OSBPL5 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 203/392 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55145209; called by muse, mutect2, varscan2
- PCLO | c.7459C>T p.P2487S | Missense Mutation (SNP) | VAF 190/479 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as COSV61658962; called by muse, mutect2, varscan2
- PIK3C2G | c.3836C>T p.S1279L (on ENST00000676171; = p.S1238L on NM_004570.5) | Missense Mutation (SNP) | VAF 335/713 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs935135637, COSV56800636, COSV56812711; called by muse, mutect2, varscan2
- PLA2G4E | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 149/339 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756536759; called by muse, mutect2, varscan2
- PLCB4 | c.2286G>A p.V762= | Splice Region (SNP) | VAF 126/268 reads (47%) | catalogued as rs1018917845; called by muse, mutect2, varscan2
- PLXNA4 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 402/703 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as COSV58166450; called by muse, mutect2, varscan2
- PRKAA2 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64802460; called by muse, mutect2, varscan2
- PTPN13 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1165333843; called by muse, mutect2, varscan2
- PTPN13 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs368916880, COSV100364898; called by muse, mutect2, varscan2
- RAVER2 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 185/362 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1443350938; called by muse, mutect2, varscan2
- RFPL4B | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 95/295 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV101480681; called by muse, mutect2, varscan2
- RGS7 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 219/522 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as rs866505496, COSV58531455; called by muse, mutect2, varscan2
- RHAG | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 212/414 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57702961; called by muse, mutect2, varscan2
- RYR1 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 214/418 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs553882104, COSV62096141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S100Z | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 165/165 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs373309306; called by muse, mutect2, varscan2
- SCN11A | c.4660G>A p.D1554N | Missense Mutation (SNP) | VAF 244/460 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56565290; called by muse, mutect2, varscan2
- SEZ6L | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 230/462 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs752901613, COSV50657778; called by muse, mutect2, varscan2
- SLC26A9 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 244/616 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755264562, COSV61602448; called by muse, mutect2, varscan2
- SLC27A6 | c.1703G>A p.G568E | Missense Mutation (SNP) | VAF 121/121 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as rs151144946; called by muse, mutect2, varscan2
- SLC27A6 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 106/106 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs1315273250, COSV52482732; called by muse, mutect2, varscan2
- SLC39A11 | c.509C>T p.P170L (on ENST00000542342 / NM_001159770.2; = p.P163L on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 318/610 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55299911; called by muse, varscan2
- SORCS3 | c.2989C>T p.H997Y | Missense Mutation (SNP) | VAF 90/200 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100863767, COSV63796584; called by muse, mutect2, varscan2
- SVEP1 | c.3338G>A p.G1113E | Missense Mutation (SNP) | VAF 91/91 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57028499; called by muse, mutect2, varscan2
- TAAR6 | c.918G>T p.M306I | Missense Mutation (SNP) | VAF 91/283 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV99256622; called by muse, mutect2, varscan2
- TBC1D10C | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 224/1481 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs371478822, COSV100408234; called by muse, mutect2, varscan2
- TBC1D2 | c.2467C>T p.R823C | Missense Mutation (SNP) | VAF 137/138 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376572846; called by muse, mutect2, varscan2
- TBC1D21 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 182/361 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.294); catalogued as COSV55995390; called by muse, mutect2, varscan2
- TRIOBP | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 334/671 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.476); catalogued as COSV60377658; called by muse, mutect2, varscan2
- TRPM7 | c.4055C>T p.S1352F | Missense Mutation (SNP) | VAF 180/420 reads (43%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.058); catalogued as rs1316733265; called by muse, mutect2, varscan2
- TTN | c.68362G>A p.E22788K (on ENST00000591111; = p.E15364K on NM_003319.4) | Missense Mutation (SNP) | VAF 292/583 reads (50%) | PolyPhen probably damaging (0.994); catalogued as rs373773552; called by muse, mutect2, varscan2
- UBE2Z | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 157/283 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs1232589217; called by muse, mutect2, varscan2
- UHRF1 | c.1354C>T p.R452W (on ENST00000612630 / NM_001290050.1; = p.R465W on NM_013282.4) | Missense Mutation (SNP) | VAF 93/285 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308222891; called by muse, mutect2, varscan2
- UNC13C | c.4304C>T p.P1435L | Missense Mutation (SNP) | VAF 154/300 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.356); catalogued as COSV52899179; called by muse, mutect2, varscan2
- VGLL3 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 210/463 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101052111; called by muse, mutect2, varscan2
- ZGRF1 | c.5714G>A p.R1905Q | Missense Mutation (SNP) | VAF 138/220 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs574383993; called by muse, mutect2, varscan2
- ZNF780B | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 194/412 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as rs747559058; called by muse, mutect2, varscan2
- ACSM2A | c.1142G>A p.G381E (on ENST00000219054; = p.G302E on NM_001308169.2) | Missense Mutation (SNP) | VAF 99/250 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTL8 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 497/925 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ACVR1C | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 226/478 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ANKRD2 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 259/567 reads (46%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ARHGAP11A | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 161/414 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP11A | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 162/415 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATG2A | c.3404C>T p.T1135I | Missense Mutation (SNP) | VAF 153/339 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C10orf71 | c.3253G>A p.G1085R | Missense Mutation (SNP) | VAF 231/551 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- C18orf63 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 163/340 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C1orf116 | c.617A>G p.D206G | Missense Mutation (SNP) | VAF 233/584 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CASKIN1 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 127/264 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC114 | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 285/554 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CDH12 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CEP131 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 185/404 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- CFAP251 | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 288/288 reads (100%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP69 | c.1099A>G p.K367E | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFTR | c.54-1G>A p.X18_splice | Splice Site (SNP) | VAF 164/385 reads (43%) | called by muse, mutect2, varscan2
- CHRNA2 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 75/302 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD2 | c.1565G>A p.G522D | Missense Mutation (SNP) | VAF 177/500 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DACH1 | c.1751C>T p.T584I (on ENST00000619232 / NM_001366712.1; = p.T330I on NM_004392.6) | Missense Mutation (SNP) | VAF 144/315 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DGCR8 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 207/412 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- EIF3G | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 291/521 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPPK1 | c.2848A>C p.M950L | Missense Mutation (SNP) | VAF 316/452 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- FAM187A | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 161/380 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- FGD2 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 238/471 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- FN1 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 292/590 reads (49%) | called by muse, mutect2, varscan2
- FZD2 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 252/543 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLT1D1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 117/325 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GPR179 | c.6490G>A p.G2164R (on ENST00000621958; = p.G2163R on NM_001004334.4) | Missense Mutation (SNP) | VAF 321/630 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.16); called by muse, varscan2
- GPX2 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 139/288 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HLA-A | c.1081_1087del p.G361Mfs*29 (on ENST00000376806; = p.G355Mfs*29 on NM_002116.8) | Frame Shift Del (DEL) | VAF 51/123 reads (41%) | called by mutect2, pindel
- IFNAR2 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 129/286 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- ITGA2 | c.2695C>T p.L899F | Missense Mutation (SNP) | VAF 160/160 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KBTBD13 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 308/631 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHDC7B | c.119G>A p.G40D (on ENST00000395676; = p.G681D on NM_138433.5) | Missense Mutation (SNP) | VAF 260/499 reads (52%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MCHR2 | c.464T>C p.L155S | Missense Mutation (SNP) | VAF 191/292 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- MIS18BP1 | c.2290A>C p.K764Q | Missense Mutation (SNP) | VAF 114/244 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- MMP24 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 263/521 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- MUC16 | c.6926C>T p.P2309L | Missense Mutation (SNP) | VAF 175/276 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYBPC3 | c.657C>T p.V219= | Splice Region (SNP) | VAF 191/348 reads (55%) | called by muse, mutect2, varscan2
- NDST4 | c.1036C>T p.L346F | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NT5C1B | c.120G>A p.Q40= | Splice Region (SNP) | VAF 210/443 reads (47%) | called by muse, mutect2, varscan2
- PCLO | c.13834G>A p.D4612N | Missense Mutation (SNP) | VAF 134/367 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- PPP1R42 | c.194T>G p.I65S | Missense Mutation (SNP) | VAF 120/203 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- PRAMEF2 | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 204/416 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PRDM9 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 191/351 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PROKR1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 318/753 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROX2 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 214/376 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RAPGEF3 | c.428G>A p.G143E (on ENST00000389212; = p.G101E on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 246/246 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- RAPGEF3 | c.427G>A p.G143R (on ENST00000389212; = p.G101R on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 245/245 reads (100%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- RAPGEF5 | c.1723A>T p.R575W (on ENST00000401957 / NM_001367602.2; = p.R878W on NM_012294.5) | Missense Mutation (SNP) | VAF 153/318 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- RAVER2 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 185/363 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- RNF17 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 100/232 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS6KB2 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 228/1387 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RTL3 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 271/271 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RTL3 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 308/308 reads (100%) | called by muse, mutect2, varscan2
- SCN2A | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 193/474 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC14L2 | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 149/307 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- SEC16B | c.1137C>T p.S379= | Splice Region (SNP) | VAF 172/297 reads (58%) | called by muse, mutect2, varscan2
- SIK2 | c.1055_1068del p.G352Afs*2 | Frame Shift Del (DEL) | VAF 112/117 reads (96%) | called by mutect2, pindel, varscan2
- SLK | c.494T>C p.L165S | Missense Mutation (SNP) | VAF 148/311 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMYD2 | c.95T>A p.L32* | Nonsense Mutation (SNP) | VAF 405/672 reads (60%) | called by muse, varscan2
- SPTBN4 | c.6689G>A p.R2230Q | Missense Mutation (SNP) | VAF 368/762 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STAMBPL1 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYNCRIP | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TENM1 | c.1788C>A p.C596* | Nonsense Mutation (SNP) | VAF 343/344 reads (100%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 217/511 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- TMEM87A | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 110/250 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TMPRSS4 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 211/213 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOP2B | c.1418C>T p.S473F (on ENST00000264331 / NM_001330700.2; = p.S468F on NM_001068.3) | Missense Mutation (SNP) | VAF 150/279 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- TRAV9-1 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 127/236 reads (54%) | SIFT tolerated (0.9); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TSPEAR | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 112/255 reads (44%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.5128C>T p.P1710S | Missense Mutation (SNP) | VAF 144/291 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- TXNDC5 | c.1024T>C p.F342L | Missense Mutation (SNP) | VAF 181/384 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2
- UNC45B | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 190/368 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS9D1 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 329/631 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- WDR47 | c.2525C>T p.S842F (on ENST00000369962 / NM_001142551.2; = p.S843F on NM_014969.5) | Missense Mutation (SNP) | VAF 306/503 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- XPR1 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 141/330 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFPM2 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 248/366 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ZFYVE27 | c.383A>T p.H128L | Missense Mutation (SNP) | VAF 193/417 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZNF316 | c.2013del p.I672Sfs*119 | Frame Shift Del (DEL) | VAF 230/384 reads (60%) | called by mutect2, pindel*, varscan2
- ZNF527 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 150/342 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF536 | c.2123G>A p.G708E | Missense Mutation (SNP) | VAF 278/580 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF808 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 121/265 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF827 | c.1535A>C p.Q512P | Missense Mutation (SNP) | VAF 119/347 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABL1 | c.2493C>T p.P831= | Silent (SNP) | VAF 280/282 reads (99%) | catalogued as COSV59335628; called by muse, mutect2, varscan2
- ADGRG6 | c.3357G>A p.E1119= | Silent (SNP) | VAF 60/217 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.288G>A p.K96= | Silent (SNP) | VAF 156/378 reads (41%) | called by muse, mutect2, varscan2
- AZIN2 | c.297C>T p.V99= | Silent (SNP) | VAF 257/499 reads (52%) | called by muse, mutect2, varscan2
- C11orf24 | c.42C>T p.S14= | Silent (SNP) | VAF 198/1374 reads (14%) | called by muse, mutect2, varscan2
- CACNA1E | c.3300G>A p.K1100= | Silent (SNP) | VAF 228/393 reads (58%) | catalogued as COSV62392622; called by muse, mutect2, varscan2
- CACNA1I | c.591C>T p.I197= | Silent (SNP) | VAF 156/348 reads (45%) | called by muse, mutect2, varscan2
- CCDC81 | c.1782G>A p.K594= (on ENST00000445632 / NM_001156474.2; = p.K504= on NM_021827.4) | Silent (SNP) | VAF 152/156 reads (97%) | called by muse, mutect2, varscan2
- CCN5 | c.747C>T p.A249= | Silent (SNP) | VAF 324/659 reads (49%) | called by muse, mutect2, varscan2
- CEP295 | c.4659C>T p.S1553= | Silent (SNP) | VAF 208/210 reads (99%) | catalogued as rs1200542669; called by muse, mutect2, varscan2
- CES3 | c.1308C>T p.V436= | Silent (SNP) | VAF 135/278 reads (49%) | called by muse, mutect2, varscan2
- CFAP251 | c.528G>A p.R176= | Silent (SNP) | VAF 287/287 reads (100%) | called by muse, mutect2, varscan2
- CHRNA2 | c.1545G>A p.G515= | Silent (SNP) | VAF 75/302 reads (25%) | catalogued as rs1246904851; called by muse, mutect2, varscan2
- CLCN1 | c.2565G>A p.G855= | Silent (SNP) | VAF 309/580 reads (53%) | catalogued as rs866583816, COSV58368943; called by muse, mutect2, varscan2
- CLGN | c.615C>T p.F205= | Silent (SNP) | VAF 104/171 reads (61%) | catalogued as rs749787516, COSV57774342; called by muse, mutect2, varscan2
- CPE | c.1068C>T p.T356= | Silent (SNP) | VAF 76/255 reads (30%) | catalogued as rs1442814949; called by muse, mutect2, varscan2
- CSPG4 | c.5049C>T p.A1683= | Silent (SNP) | VAF 243/542 reads (45%) | called by muse, mutect2, varscan2
- CYP2C19 | c.300C>T p.F100= | Silent (SNP) | VAF 160/349 reads (46%) | catalogued as rs774817817, COSV64909645; called by muse, mutect2, varscan2
- DAB2IP | c.2415G>A p.Q805= (on ENST00000408936; = p.Q777= on NM_032552.3) | Silent (SNP) | VAF 325/327 reads (99%) | called by muse, mutect2, varscan2
- DACH1 | c.1752C>T p.T584= (on ENST00000619232 / NM_001366712.1; = p.T330= on NM_004392.6) | Silent (SNP) | VAF 146/321 reads (45%) | catalogued as rs757570915; called by muse, mutect2, varscan2
- DACH1 | c.507G>A p.G169= | Silent (SNP) | VAF 232/443 reads (52%) | called by muse, varscan2
- DAPK2 | c.765C>T p.S255= | Silent (SNP) | VAF 208/458 reads (45%) | catalogued as rs555502296; called by muse, mutect2, varscan2
- DDX43 | c.1008T>C p.C336= | Silent (SNP) | VAF 117/182 reads (64%) | called by muse, mutect2, varscan2
- DDX60L | c.88T>C p.L30= | Silent (SNP) | VAF 89/150 reads (59%) | catalogued as rs760314085; called by muse, mutect2, varscan2
- DGKK | c.1089G>A p.V363= | Silent (SNP) | VAF 125/125 reads (100%) | catalogued as COSV65709663; called by muse, mutect2, varscan2
- DMWD | c.1506G>T p.G502= | Silent (SNP) | VAF 272/580 reads (47%) | called by muse, mutect2, varscan2
- DNAH5 | c.2532C>T p.P844= | Silent (SNP) | VAF 152/348 reads (44%) | called by muse, mutect2, varscan2
- DNAH8 | c.12333C>T p.I4111= | Silent (SNP) | VAF 147/355 reads (41%) | catalogued as rs746148886; called by muse, mutect2, varscan2
- DPP3 | c.1743G>A p.E581= | Silent (SNP) | VAF 192/711 reads (27%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.6720A>G p.A2240= | Silent (SNP) | VAF 167/320 reads (52%) | called by muse, mutect2, varscan2
- EBLN1 | c.384C>T p.F128= | Silent (SNP) | VAF 237/238 reads (100%) | called by muse, mutect2, varscan2
- ELFN1 | c.930C>T p.A310= | Silent (SNP) | VAF 380/780 reads (49%) | called by muse, mutect2, varscan2
- FAM71F1 | c.154C>T p.L52= | Silent (SNP) | VAF 428/817 reads (52%) | catalogued as rs528519122; called by muse, mutect2, varscan2
- FAT1 | c.2967G>A p.L989= | Silent (SNP) | VAF 114/320 reads (36%) | called by muse, mutect2, varscan2
- FPR2 | c.327C>T p.L109= | Silent (SNP) | VAF 204/393 reads (52%) | called by muse, varscan2
- GALNT2 | c.354C>T p.I118= | Silent (SNP) | VAF 75/398 reads (19%) | called by muse, mutect2, varscan2
- H1-4 | c.570G>A p.K190= | Silent (SNP) | VAF 199/389 reads (51%) | catalogued as rs1329149804; called by muse, mutect2, varscan2
- HACL1 | c.1623C>T p.S541= | Silent (SNP) | VAF 474/832 reads (57%) | catalogued as COSV58256824; called by muse, mutect2, varscan2
- HARBI1 | c.57C>T p.H19= | Silent (SNP) | VAF 202/425 reads (48%) | catalogued as COSV56319144, COSV56319938; called by muse, mutect2, varscan2
- HMCN1 | c.15105C>T p.I5035= | Silent (SNP) | VAF 190/501 reads (38%) | catalogued as COSV54939079; called by muse, mutect2, varscan2
- IGHV2-26 | c.282C>T p.T94= | Silent (SNP) | VAF 142/339 reads (42%) | catalogued as rs1555476482; called by muse, mutect2, varscan2
- JPH3 | c.588C>T p.F196= | Silent (SNP) | VAF 267/518 reads (52%) | catalogued as rs747932359, COSV52467894; called by muse, mutect2, varscan2
- KCNK10 | c.1179C>T p.S393= | Silent (SNP) | VAF 210/413 reads (51%) | catalogued as rs775302473, COSV56646847; called by muse, mutect2, varscan2
- KRT79 | c.1068G>A p.R356= | Silent (SNP) | VAF 299/299 reads (100%) | called by muse, mutect2, varscan2
- LDAH | c.69C>T p.T23= | Silent (SNP) | VAF 301/641 reads (47%) | called by muse, mutect2, varscan2
- LNX1 | c.897C>T p.V299= (on ENST00000263925 / NM_001126328.3; = p.V203= on NM_032622.2) | Silent (SNP) | VAF 219/300 reads (73%) | catalogued as COSV55781557; called by muse, mutect2, varscan2
- LRFN2 | c.2259G>A p.T753= | Silent (SNP) | VAF 236/505 reads (47%) | catalogued as rs773172303, COSV57823747, COSV57825855; called by muse, mutect2, varscan2
- LUZP2 | c.930C>T p.I310= | Silent (SNP) | VAF 94/240 reads (39%) | catalogued as rs1422495454, COSV100419390; called by muse, mutect2
- MARCHF1 | c.33C>T p.N11= | Silent (SNP) | VAF 126/193 reads (65%) | catalogued as rs1456325913, COSV56808678; called by muse, mutect2, varscan2
- MICALL2 | c.1860C>T p.A620= | Silent (SNP) | VAF 261/555 reads (47%) | catalogued as rs1047776502, COSV52519890; called by muse, mutect2, varscan2
- MRPS31 | c.450C>T p.P150= | Silent (SNP) | VAF 115/241 reads (48%) | called by muse, mutect2, varscan2
- NPC2 | c.231C>T p.I77= | Silent (SNP) | VAF 180/324 reads (56%) | called by muse, mutect2, varscan2
- NRXN1 | c.390C>T p.I130= | Silent (SNP) | VAF 338/714 reads (47%) | catalogued as COSV67999796; called by muse, mutect2, varscan2
- NUMA1 | c.5133G>A p.E1711= | Silent (SNP) | VAF 238/1162 reads (20%) | catalogued as rs777619697; called by muse, mutect2, varscan2
- NUMA1 | c.246A>G p.V82= | Silent (SNP) | VAF 168/891 reads (19%) | catalogued as rs1382208263; called by muse, mutect2, varscan2
- NUTM2A | c.882C>T p.S294= | Silent (SNP) | VAF 121/482 reads (25%) | catalogued as rs1433390938; called by muse, mutect2, varscan2
- OR10H3 | c.933C>T p.F311= | Silent (SNP) | VAF 52/141 reads (37%) | catalogued as rs765259784; called by muse, mutect2, varscan2
- OR2G3 | c.906G>A p.R302= | Silent (SNP) | VAF 64/221 reads (29%) | catalogued as COSV60680702; called by muse, mutect2, varscan2
- OR2W1 | c.294C>T p.I98= | Silent (SNP) | VAF 172/389 reads (44%) | catalogued as COSV101013932; called by muse, mutect2, varscan2
- OR4X2 | c.565C>T p.L189= | Silent (SNP) | VAF 253/524 reads (48%) | called by muse, mutect2, varscan2
- OR51D1 | c.183C>T p.I61= | Silent (SNP) | VAF 265/547 reads (48%) | called by muse, mutect2, varscan2
- OR8D2 | c.93C>T p.F31= | Silent (SNP) | VAF 193/194 reads (99%) | catalogued as rs148447195; called by muse, mutect2, varscan2
- PCDHGA10 | c.675C>T p.L225= | Silent (SNP) | VAF 194/194 reads (100%) | called by muse, mutect2, varscan2
- PIK3C2G | c.3162G>A p.R1054= (on ENST00000676171; = p.R1013= on NM_004570.5) | Silent (SNP) | VAF 144/297 reads (48%) | catalogued as rs372691815; called by muse, mutect2, varscan2
- PKHD1L1 | c.5094C>T p.F1698= | Silent (SNP) | VAF 77/263 reads (29%) | catalogued as COSV65744776; called by muse, mutect2, varscan2
- PRSS36 | c.2343C>T p.L781= | Silent (SNP) | VAF 243/532 reads (46%) | called by muse, mutect2, varscan2
- PTPRB | c.2781C>T p.N927= | Silent (SNP) | VAF 225/225 reads (100%) | catalogued as rs749431250; called by muse, mutect2, varscan2
- PTPRK | c.2220C>T p.I740= (on ENST00000368215 / NM_001291984.2; = p.I741= on NM_002844.4) | Silent (SNP) | VAF 81/295 reads (27%) | called by muse, mutect2, varscan2
- RASA4B | c.390C>T p.A130= | Silent (SNP) | VAF 152/1140 reads (13%) | catalogued as rs1205737098; called by muse, mutect2
- RECQL4 | c.825C>T p.V275= | Silent (SNP) | VAF 328/496 reads (66%) | called by muse, mutect2, varscan2
- RNASEL | c.291C>T p.I97= | Silent (SNP) | VAF 185/482 reads (38%) | catalogued as rs776694567, COSV62377953; called by muse, mutect2, varscan2
- RPP25L | c.432C>T p.S144= | Silent (SNP) | VAF 321/322 reads (100%) | called by muse, mutect2, varscan2
- RTL3 | c.708C>T p.F236= | Silent (SNP) | VAF 272/272 reads (100%) | catalogued as COSV58186020; called by muse, mutect2, varscan2
- SALL4 | c.2145C>T p.I715= | Silent (SNP) | VAF 257/550 reads (47%) | called by muse, mutect2, varscan2
- SCN10A | c.3705G>A p.A1235= | Silent (SNP) | VAF 152/393 reads (39%) | catalogued as rs147376215; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC8A3 | c.1767C>T p.F589= | Silent (SNP) | VAF 133/257 reads (52%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.978C>T p.F326= | Silent (SNP) | VAF 139/286 reads (49%) | catalogued as COSV57007664; called by muse, mutect2, varscan2
- SLCO5A1 | c.1488G>A p.L496= | Silent (SNP) | VAF 91/293 reads (31%) | catalogued as COSV52664817; called by muse, mutect2, varscan2
- SMAD6 | c.1161C>T p.I387= | Silent (SNP) | VAF 339/695 reads (49%) | catalogued as rs777669717, COSV56596181; called by muse, mutect2, varscan2
- SMG1 | c.8781C>T p.I2927= | Silent (SNP) | VAF 105/228 reads (46%) | catalogued as rs767813326; called by muse, mutect2, varscan2
- SNX15 | c.237C>T p.F79= | Silent (SNP) | VAF 169/337 reads (50%) | catalogued as rs368357639; called by muse, mutect2, varscan2
- STAMBPL1 | c.372C>T p.D124= | Silent (SNP) | VAF 27/97 reads (28%) | called by muse, mutect2, varscan2
- TAFA4 | c.237C>T p.F79= | Silent (SNP) | VAF 182/418 reads (44%) | catalogued as COSV55145871; called by muse, mutect2, varscan2
- TBC1D10C | c.114C>T p.D38= | Silent (SNP) | VAF 224/1505 reads (15%) | catalogued as rs776470617; called by muse, mutect2, varscan2
- TESMIN | c.1299G>A p.T433= | Silent (SNP) | VAF 187/1314 reads (14%) | catalogued as rs867073198, COSV54835687, COSV99663274; called by muse, mutect2, varscan2
- TF | c.2067C>T p.L689= | Silent (SNP) | VAF 73/73 reads (100%) | called by muse, mutect2, varscan2
- TMC5 | c.2958A>G p.E986= (on ENST00000396229 / NM_001105248.1; = p.E740= on NM_024780.5) | Silent (SNP) | VAF 135/312 reads (43%) | called by muse, mutect2, varscan2
- TMCC3 | c.1305C>T p.F435= | Silent (SNP) | VAF 342/342 reads (100%) | catalogued as rs759224978, COSV54153365; called by muse, mutect2, varscan2
- TMPRSS3 | c.258C>T p.I86= | Silent (SNP) | VAF 264/493 reads (54%) | catalogued as rs192083827; called by muse, mutect2, varscan2
- TNXB | c.5553C>T p.F1851= (on ENST00000647633; = p.F1604= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 198/396 reads (50%) | catalogued as rs536054720, COSV64476347; called by muse, mutect2, varscan2
- TOP2B | c.1419C>T p.S473= (on ENST00000264331 / NM_001330700.2; = p.S468= on NM_001068.3) | Silent (SNP) | VAF 149/279 reads (53%) | catalogued as rs1305365873; called by muse, mutect2, varscan2
- TRANK1 | c.5286G>A p.K1762= | Silent (SNP) | VAF 210/478 reads (44%) | called by muse, mutect2, varscan2
- TRAV4 | c.243C>T p.I81= | Silent (SNP) | VAF 184/299 reads (62%) | called by muse, mutect2, varscan2
- TSPEAR | c.726C>T p.I242= | Silent (SNP) | VAF 296/568 reads (52%) | catalogued as rs1555915501; called by muse, mutect2, varscan2
- TXNDC5 | c.1026C>T p.F342= | Silent (SNP) | VAF 180/381 reads (47%) | catalogued as rs1320177386, COSV51669787; called by muse, mutect2
- UNC13A | c.2016C>T p.S672= | Silent (SNP) | VAF 199/288 reads (69%) | catalogued as rs1467271204; called by muse, mutect2, varscan2
- UNC13C | c.4305C>T p.P1435= | Silent (SNP) | VAF 155/303 reads (51%) | catalogued as rs376495525; called by muse, mutect2, varscan2
- UNC45B | c.1227C>T p.P409= | Silent (SNP) | VAF 191/373 reads (51%) | catalogued as rs1481523440; called by muse, mutect2, varscan2
- UNC79 | c.7821C>T p.L2607= (on ENST00000393151 / NM_001346218.2; = p.L2430= on NM_020818.5) | Silent (SNP) | VAF 229/554 reads (41%) | called by muse, mutect2, varscan2
- ZFHX2 | c.678G>A p.G226= | Silent (SNP) | VAF 227/471 reads (48%) | catalogued as rs1406854888; called by muse, mutect2, varscan2
- ZGRF1 | c.2034C>T p.P678= | Silent (SNP) | VAF 53/221 reads (24%) | called by muse, mutect2, varscan2
- ZKSCAN3 | c.384G>A p.L128= | Silent (SNP) | VAF 133/274 reads (49%) | called by muse, mutect2, varscan2
- ZNF333 | c.1077C>T p.I359= | Silent (SNP) | VAF 209/463 reads (45%) | catalogued as COSV99468650; called by muse, mutect2, varscan2
- ZNF44 | c.495C>T p.S165= (on ENST00000356109 / NM_001164276.2; = p.S117= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 194/432 reads (45%) | called by muse, mutect2
- ZNF699 | c.885A>G p.T295= | Silent (SNP) | VAF 221/349 reads (63%) | catalogued as rs1244717366; called by muse, varscan2
- ZNF703 | c.1494C>T p.P498= | Silent (SNP) | VAF 326/513 reads (64%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.-295G>A | 5'UTR (SNP) | VAF 215/296 reads (73%) | catalogued as rs1178310406; called by muse, mutect2, varscan2
- GNAS | chr20:58850764 C>T | 5'Flank (SNP) | VAF 283/603 reads (47%) | catalogued as rs1182143365; called by muse, mutect2, varscan2
- INTS8 | c.*646C>G | 3'UTR (SNP) | VAF 37/287 reads (13%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-33690C>T | Intron (SNP) | VAF 156/311 reads (50%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+29993C>T | Intron (SNP) | VAF 201/393 reads (51%) | catalogued as rs898585464; called by muse, mutect2, varscan2
- OCIAD1 | c.547+13C>T | Intron (SNP) | VAF 52/170 reads (31%) | called by muse, mutect2, varscan2
- SCN1B | c.448+348G>A | Intron (SNP) | VAF 111/254 reads (44%) | called by muse, mutect2, varscan2
- SYT7 | c.215+5198G>A | Intron (SNP) | VAF 292/605 reads (48%) | called by muse, mutect2, varscan2
